Gene-level copy-number profile of tumor specimen TCGA-13-0794-01A from TCGA case TCGA-13-0794, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 60.1 years (21,945 days).
Specimen TCGA-13-0794-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8568dd65-84a3-45e4-8a68-dd75afa5a8bc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0794-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bfb1b8f0-4761-4da9-8c04-dbdfd4502ef0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 270; copy number 2: 7,118; copy number 3: 21,253; copy number 4: 23,652; copy number 5: 3,500; copy number 6: 2,545; copy number 7: 653; copy number 8: 598; copy number 9: 99; copy number 10: 61; copy number 11: 16; copy number 15: 48.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0794-01A-01D-0356-01): tumor purity 0.93, ploidy 3.53, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 213 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:27,534,035–28,282,491, 38 genes, copy number 9 (within-gene range 1–9): AHDC1, FGR, AL031729.1, LINC02574, IFI6, AL445490.1, RNU6-949P, CHMP1AP1, RNU6-424P, AL020997.5, FAM76A, AL020997.1, RPEP3, STX12, AL020997.2, AL020997.3, RNU6-1245P, AL020997.4, PPP1R8, SCARNA1, THEMIS2, RPA2, SMPDL3B, AL512288.1, XKR8, EYA3, AL512288.2, RN7SL559P, SPCS2P4, AL137792.2, AL137792.1, RNU6-176P, PTAFR, DNAJC8, ATP5IF1, AL353622.1, AL353622.2, SESN2.
- chr3:169,003,022–169,038,416, 1 gene, copy number 9: LINC01997.
- chr4:152,779,937–152,918,463, 1 gene, copy number 9 (within-gene range 4–9): ARFIP1.
- chr4:152,927,446–153,415,118, 11 genes, copy number 9: FAM192BP, AC093599.2, FHDC1, AC093599.1, TRIM2, AC013477.1, RNU6-1196P, Y_RNA, ANXA2P1, MND1, RN7SL419P.
- chr9:128,528,657–129,380,470, 43 genes, copy number 10: AL356481.1, RNU7-171P, SPTAN1, AL356481.2, AL356481.3, DYNC2I2, VTI1BP4, HMGA1P4, SET, PKN3, RN7SL560P, ZDHHC12, AL441992.1, ZER1, Metazoa_SRP, TBC1D13, ENDOG, SPOUT1, AL441992.2, KYAT1, LRRC8A, PHYHD1, AL672142.1, DOLK, NUP188, AL592211.1, SH3GLB2, MIGA2, AL592211.2, DOLPP1, CRAT, AL158151.2, PTPA, AL158151.3, AL158151.4, IER5L, AL158151.1, AL161785.1, C9orf106, AL353803.5, LINC01503, RN7SL159P, AL353803.3.
- chr12:31,647,160–31,853,407, 10 genes, copy number 9: ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3.
- chr12:31,893,370–31,898,123, 2 genes, copy number 9: AC023050.4, AC023050.1.
- chr12:121,580,792–121,874,337, 14 genes, copy number 9: KDM2B-DT, RNU6-1004P, ORAI1, MORN3, AC084018.3, TMEM120B, RHOF, LINC01089, AC084018.1, AC084018.2, SETD1B, HPD, AC079360.1, AC069503.3.
- chr17:28,662,198–29,404,105, 48 genes, copy number 15 (within-gene range 2–15): SUPT6H, AC010761.3, PROCA1, RAB34, RPL23A, SNORD42B, AC010761.1, SNORD4A, SNORD42A, SNORD4B, TLCD1, NEK8, AC010761.6, AC010761.2, TRAF4, AC010761.4, AC010761.5, FAM222B, RPL31P58, Y_RNA, AC024267.2, ERAL1, AC024267.1, MIR451A, MIR451B, MIR144, MIR4732, FLOT2, AC024267.3, AC024267.6, DHRS13, PHF12, AC024267.4, AC024267.5, PIPOX, SEZ6, AC024619.2, AC024619.1, AC024619.4, MYO18A, TIAF1, AC024619.3, AC005412.1, TWF1P1, CRYBA1, NUFIP2, RPL35AP35, AC068025.2.
- chr19:29,665,459–30,029,916, 11 genes, copy number 9: PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2.
- chr20:46,099,518–47,493,085, 34 genes, copy number 10–11: RPL13P2, CD40, AL031687.1, CDH22, SLC35C2, AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP, SLC13A3, AL133520.1, TP53RK, AL031055.1, SLC2A10, RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P.

Autosomal genes at a single copy (total copy number 1): 270. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
